Somatic mutation profile of tumor specimen TCGA-EM-A22N-01A (aliquot TCGA-EM-A22N-01A-11D-A17V-08) from TCGA case TCGA-EM-A22N, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 68.5 years (25,035 days).
Specimen TCGA-EM-A22N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5111a6d-105a-4efe-a20c-c4332a64c5d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A22N-10A (Blood Derived Normal), aliquot TCGA-EM-A22N-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf5aa5da-daa9-44fa-8fcb-9523f7f97464

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.767G>A p.C256Y | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64209593; called by muse, mutect2, varscan2
- OR5AK2 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.873); catalogued as rs775272882, COSV100475876, COSV58803628; called by muse, mutect2, varscan2
- OR5AK2 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100476042; called by muse, mutect2, varscan2
- SLC38A7 | c.1293G>T p.W431C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.923); catalogued as COSV54704459; called by muse, mutect2
- TRIM46 | c.2039C>T p.T680I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV58117810; called by muse, mutect2, varscan2
- LSAMP | c.374A>T p.Y125F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- KIF2A | c.255A>T p.S85= | Silent (SNP) | VAF 7/124 reads (6%) | catalogued as COSV66946476; called by muse, mutect2
- SINHCAF | c.405T>G p.P135= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV61797681; called by muse, mutect2, varscan2
